Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A8AS, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A8AS-01A (Primary Tumor).

[page 1 of 4]
Age: [redacted] years Sex: Male

Print Date:

Date Collected:

Date Received:

Accession [redacted]

Physician:

Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
[redacted]				

Clinical Information

year old male with mesothelioma; Right Thoracotomy, Bronchoscopy, PDT

Final Diagnosis

1. RIB:

Benign lamellar bone with trilinear bone marrow formation present.

2. PERICARDIAL FAT:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type

3. PERICARDIUM:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type

4. PHRENIC NODE:

Fibrofatty soft tissue and sections of lymph node, no tumor seen
Confirmed by immunohistochemical stain

5. DIAPHRAGM:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type

6. VISCERAL PLEURA:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type
Overlying lung without definite parenchymal involvement
See comment

7. LEVEL 7:

Sections of lymph node, no tumor seen
Confirmed by immunohistochemical stain

8. LEVEL 9:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type

9. LEVEL 4:

Sections of lymph node, no tumor seen
Confirmed by immunohistochemical stain

10. POSTERIOR INTERCOSTAL:

Sections of lymph node, no tumor seen

ICD-O-3

Mesothelioma, epithelioid
malignant 9052/3

Site: Pleura NOS 038.4

Y-5/28/14

Na [redacted]
MRN [redacted]

[page 2 of 4]
Print Date:
Date Collected:
Date Received:
Accession N
Physician:
Copy to:

Age: years Sex: Male

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Confirmed by immunohistochemical stain

11. PLEURA:

Fibrofatty soft tissue with presence of malignant mesothelioma, epithelioid type

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Note

Tumor is positive for Calretinin, WT1, AE1-3, D2-40, CK5/6 and minimally for CK7, and negative for CEA, CD15TTF1 and MOC-31 confirming presence of mesothelioma.

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the ... This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Synoptic Report

Mesothelioma

Site:
Right

Histologic Type
Epithelioid (epithelial) mesothelioma

Margins
Cannot be assessed

Name
MRN

[page 3 of 4]
Print Date:

Date Collected:

Date Received:

Accession N

Physician:

Copy to:

Age: years Sex: Male

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Lymph nodes

Specify: Number examined: 4 levels
Number involved: 0

Pathologic Staging (pT1A N0 MX)

Gross Description

The specimen is received in 11 parts in formalin in a container labeled with the patient's name and medical record number.

Specimen #1 is designated "Rib" and consists of a fragment of bone measuring 3.5 x 1.7 x 0.5 cm. Representative sections are submitted in Block #1 for decalcification.

Specimen #2 is designated "Pericardial Fat" and consists of multiple fragments of yellow lobulated tissue measuring in aggregate 8.5 x 6.5 x 3.5 cm. Representative sections are submitted in Blocks 2A through 2C.

Specimen #3 is designated "Pericardium" and consists of fragment of yellow lobulated tissue measuring 1.7 x 1.1 x 0.1 cm. Entirely submitted in Block #3.

Specimen #4 is designated "Phrenic Node" and consists of a fragment of yellow lobulated tissue measuring 0.9 x 0.7 x 0.5 cm. Entirely submitted in Block #4.

Specimen #5 is designated "Diaphragm" and consists of fragments of yellow lobulated tissue measuring in aggregate 7.2 x 3.7 x 2.5 cm. Representative sections are submitted in Blocks 5A through 5C.

Specimen #6 is designated "Visceral Pleura" and consists of a fragment of grayish-brown tissue measuring 5.5 x 2.8 x 1.7 cm. Representative sections are submitted in Blocks 6A and 6B.

Specimen #7 is designated "Level 7" and consists of fragment of grayish-brown tissue measuring 1.1 x 1.7 x 1.5 cm. The specimen is bisected and entirely submitted in Block 7A.

Specimen #8 is designated "Level 9" and consists of fragment of grayish-brown tissue measuring 0.7 x 1.1 x 0.2 cm. The specimen is entirely submitted in Block 8A.

Specimen #9 is designated "Level 4" and consists of two fragments of grayish-brown tissue measuring in aggregate 1.7 x 2.1 x 1.9 cm. The specimen is bisected and entirely submitted in Block #9.

Specimen #10 is designated "Posterior Intercostal" and consists of fragments of grayish-brown tissue measuring in aggregate 1.7 x 2.5 x 0.9 cm. The specimen is entirely submitted in Block #10.

Name
MR

[page 4 of 4]
[REDACTED]

years Sex: Male

Print Date:
Date Collected:
Date Received:
Accession N [REDACTED]
Physician:
Copy to:

Surgical Pathology Report

Accession Number [REDACTED] Collection Date/Time Received Date/Time Verified Date/Time Pathologist

Specimen #11 is designated "Pleura" and consists of multiple fragments of pleura and fibrofatty soft tissue. The entire specimen measures approximately 36.0 x up to 22.0 x up to 1.7 cm. The specimen shows areas of indurated pleural tissue, other areas of thin normal appearing pleura and areas of adipose tissue. Representative sections are submitted in Blocks A through C.

Dictated by

Dictated by:

Pathologist(s)

(Prior bx only.)

Diagnosis Discrepancy	lu 10/24/13	✓
Prior Malignancy History	Base cell	✓
Dual/Synchronous Primary	Noted	✓

Name [REDACTED]
MRN: [REDACTED]

Source: NCI Genomic Data Commons file ae73258b-05e5-4a61-acfa-f7da126ad595 (TCGA-TS-A8AS.28EF5137-69F0-4F69-95AF-8B604EDE9DD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).